Gene-level copy-number profile of tumor specimen BLGSP-71-19-00128-09A.1 from CGCI case BLGSP-71-19-00128, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 15.7 years (5,732 days).
Specimen BLGSP-71-19-00128-09A.1: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Sorted Cells; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 042898fc-f9e8-4e0f-a58e-e426a6a1470b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-19-00128-16A.1 (mononuclear cells from bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,729 have no estimate.
https://portal.gdc.cancer.gov/files/fc99099c-dd17-4588-b8fd-0f38be90155b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,705; copy number 2: 54,607; copy number 3: 345; copy number 4: 114; copy number 5: 11; copy number 6: 47; copy number 7: 6; copy number 9: 14; copy number 11: 8; copy number 18: 9; copy number 29: 28.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 123 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,239,580–38,329,643, 14 genes, copy number 9: TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2.
- chr7:142,670,740–142,802,748, 24 genes, copy number 6 (within-gene range 4–6): TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBC2.
- chr14:21,941,128–22,487,245, 61 genes, copy number 5–29 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 29: TRAC.
- chr19:812,488–821,955, 1 gene, copy number 6 (within-gene range 1–6): PLPPR3.
- chr19:825,097–1,095,380, 22 genes, copy number 6: AZU1, PRTN3, ELANE, CFD, MED16, RNU6-9, R3HDM4, KISS1R, ARID3A, AC005379.1, AC005391.1, WDR18, AC004528.1, GRIN3B, TMEM259, AC004528.2, RNU6-2, CNN2, AC011558.1, ABCA7, ARHGAP45, POLR2E.

Autosomal genes at a single copy (total copy number 1): 849. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
